Somatic mutation profile of tumor specimen TARGET-30-PANRHJ-01A (aliquot TARGET-30-PANRHJ-01A-01W) from TARGET case TARGET-30-PANRHJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 3.1 years (1,117 days).
Specimen TARGET-30-PANRHJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e69f0f9-08e7-4acf-be8f-05186ec46802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANRHJ-10A (Blood Derived Normal), aliquot TARGET-30-PANRHJ-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5593e67d-64bc-43d2-ad0b-34c547ca382f

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKN2 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 136/618 reads (22%) | catalogued as COSV60130165; called by muse, mutect2, varscan2
- TRAV27 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.645); catalogued as rs374728616; called by muse, mutect2
- ZNF251 | c.989T>G p.F330C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52956458; called by muse, mutect2, varscan2
- GCC1 | c.888C>G p.T296= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV50000376; called by muse, mutect2, varscan2
- TBC1D1 | c.1116G>A p.T372= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs745480598, COSV54714856, COSV54716871; called by muse, mutect2, varscan2
